Gene-level copy-number profile of tumor specimen ALCH-AC12-TTP1-A from ALCHEMIST case ALCH-AC12, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,942 days).
Specimen ALCH-AC12-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4dbd55ff-ed72-43e9-a84c-c3f35bc8d654.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AC12-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/d32db4df-d7b5-4629-80e7-723acea83c55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 11,955; copy number 2: 45,528; copy number 3: 1,276; copy number 4: 95; copy number 5: 15.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:113,008,778–113,010,319, 2 genes (within-gene range 0–1): AL356740.2, AL356740.3.
- chr14:103,519,667–103,537,073, 3 genes: CKB, AL133367.1, TRMT61A.
- chr15:25,189,414–25,225,284, 20 genes (within-gene range 0–2): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–1): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr22:18,906,028–18,959,512, 5 genes: DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:76,162,119–77,537,290, 15 genes, copy number 5: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.

Autosomal genes at a single copy (total copy number 1): 9,112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
